Somatic mutation profile of tumor specimen TCGA-CH-5767-01A (aliquot TCGA-CH-5767-01A-11D-1786-08) from TCGA case TCGA-CH-5767, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.5 years (24,287 days).
Specimen TCGA-CH-5767-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b78c93fb-8f1b-4861-969f-e4f5cbc208d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5767-11B (Solid Tissue Normal), aliquot TCGA-CH-5767-11B-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5444408b-5a77-4d3e-a613-9e4b8836c10b

The open-access MAF lists 40 somatic variants for this specimen: 32 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Nonsense Mutation 3, 5'UTR 1, Translation Start Site 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SEC61A1 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as rs879255648, COSV54579523; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP21 | c.3755C>G p.P1252R | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57612251; called by mutect2, varscan2
- BBS4 | c.437T>A p.I146K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV51440882; called by muse, mutect2, varscan2
- BIRC6 | c.13979A>C p.Y4660S | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70207664; called by muse, mutect2
- BTBD9 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 4/41 reads (10%) | catalogued as rs773093124, COSV58429089; called by mutect2, varscan2
- CHD1 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52337905; called by muse, mutect2, varscan2
- CSMD3 | c.8441C>T p.A2814V (on ENST00000297405 / NM_001363185.1; = p.A2645V on NM_052900.3) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs369949755, COSV52096577; called by muse, mutect2, varscan2
- FCSK | c.2221C>T p.R741* | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs562205568, COSV55376375; called by muse, mutect2, varscan2
- ITIH2 | c.2032A>G p.I678V | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV64433097; called by muse, mutect2, varscan2
- LHFPL6 | c.301C>T p.L101F | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV65447652; called by muse, mutect2
- MED1 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as rs1464270243, COSV56123084; called by muse, mutect2, varscan2
- MOCS1 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 154/360 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57940792; called by muse, mutect2, varscan2
- MRPL15 | c.275A>C p.Q92P | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV52636871, COSV52639059; called by muse, mutect2, varscan2
- MYLIP | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV62767850; called by muse, mutect2
- NKX3-1 | c.398A>C p.H133P | Missense Mutation (SNP) | VAF 90/123 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66512998; called by muse, mutect2, varscan2
- NOTCH2 | c.537T>A p.C179* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV56705599, COSV56709780; called by muse, mutect2
- OR2T6 | c.659G>T p.R220M | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.583); catalogued as COSV100861657, COSV63217207; called by muse, mutect2
- PIP5K1C | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as COSV58956701; called by muse, mutect2, varscan2
- PSG2 | c.370A>G p.I124V | Missense Mutation (SNP) | VAF 26/317 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.402); catalogued as COSV68885450; called by muse, mutect2
- SCAI | c.919G>C p.E307Q (on ENST00000336505 / NM_001144877.3; = p.E330Q on NM_173690.5) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs766263609, COSV60619163; called by muse, mutect2, varscan2
- SLC6A5 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54233640; called by muse, mutect2, varscan2
- SLC7A4 | c.1337G>A p.G446D | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV60386705; called by muse, mutect2, varscan2
- TAOK2 | c.1606G>T p.G536W | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV54242276; called by muse, mutect2
- TJP2 | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV55275983; called by muse, mutect2
- TPH1 | c.66T>G p.F22L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.338); catalogued as COSV51461168; called by muse, varscan2
- TSHZ2 | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV61592428; called by muse, mutect2, varscan2
- TSPOAP1 | c.4894G>T p.A1632S | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52120183; called by muse, mutect2
- TTN | c.93238G>A p.V31080I (on ENST00000591111; = p.V23656I on NM_003319.4) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | PolyPhen possibly damaging (0.528); catalogued as rs533651182, COSV60034958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UHRF1 | c.1583G>A p.R528Q (on ENST00000612630 / NM_001290050.1; = p.R541Q on NM_013282.4) | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs377699288; called by muse, mutect2, varscan2
- ZNF621 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1448597746, COSV59459461; called by muse, mutect2, varscan2
- BATF | c.-1_12del | Translation Start Site (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel, varscan2
- CHD6 | c.1442dup p.N481Kfs*6 | Frame Shift Ins (INS) | VAF 62/183 reads (34%) | called by mutect2, pindel, varscan2
- CD82 | c.273C>T p.F91= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV57037920; called by muse, mutect2, varscan2
- DRD5 | c.339C>T p.C113= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV58580951; called by muse, mutect2, varscan2
- EIF4H | c.462C>T p.F154= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV56083830; called by muse, mutect2, varscan2
- HNRNPL | c.822T>C p.N274= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as rs1206093843, COSV55491737, COSV55496026; called by muse, mutect2, varscan2
- SIGLEC5 | c.1197C>T p.H399= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs1011645346, COSV55781361; called by muse, mutect2
- TTN | c.22116C>T p.D7372= (on ENST00000591111; = p.D6445= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs191854953, COSV60027381; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CSH1 | c.457-61G>A | Intron (SNP) | VAF 49/109 reads (45%) | catalogued as COSV60243139; called by muse, mutect2, varscan2
- XIRP2 | c.-89C>T | 5'UTR (SNP) | VAF 29/75 reads (39%) | catalogued as rs1360331676, COSV54719203; called by muse, mutect2, varscan2
